Surgical pathology report (de-identified scan), TCGA case TCGA-HZ-8005, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HZ-8005-01A (Primary Tumor).

[page 1 of 5]
Diagnosis:

- A. - E.) PANCREAS, DUODENUM, DISTAL STOMACH, GALLBLADDER, APPENDIX, CELIAC LYMPH NODE, PANCREATODUODENECTOMY (WHIPPLE RESECTION), TOTAL PANCREATECTOMY, DISTAL GASTRECTOMY, CHOLECYSTECTOMY, APPENDECTOMY AND REGIONAL LYMPH NODE DISSECTION:
- POORLY DIFFERENTIATED ADENOCARCINOMA.
- 4.5 cm in greatest dimension.
- Involves pancreatic head and portion of pancreatic body.
- Invades ampulla of Vater, duodenal wall, duodenal mucosa, and invades peripancreatic soft tissue.
- MARGIN STATUS: POSITIVE.
- Tumor focally extends to the inferior anterior margin.
- All other margins negative for tumor.
- PERINEURAL INVASION: PRESENT.
- EIGHT OF TWENTY-FOUR TOTAL LYMPH NODES, POSITIVE FOR METASTATIC CARCINOMA (8/24).
- CHRONIC CHOLECYSTITIS.
- FIBROUS LUMINAL OBLITERATION OF APPENDICEAL TIP.
- SEE TUMOR STAGING SUMMARY BELOW.

PATHOLOGIC TUMOR STAGING SUMMARY:

Type and grade: Ductal adenocarcinoma, poorly differentiated.

Primary tumor: pT3 (tumor invades ampulla of Vater, duodenal wall, duodenal mucosa and peripancreatic soft tissue).

Regional lymph nodes: pN1 (twenty-four lymph nodes; eight positive for metastasis).

Distant metastasis: Not applicable.

Pathologic stage: IIB.

Lymphovascular invasion: Not identified.

Margin status: R1 (tumor focally extends to inferior anterior margin).

[page 2 of 5]
FINAL SURGICAL PATHOLOGY REPORT

Tumor Staging Information

Data derived from current specimen. Staging in accordance with or modified from AJCC Cancer Staging Handbook, [REDACTED] and CAP protocol [REDACTED]

Specimen:	Head, body, and tail of pancreas, duodenum, distal stomach, gallbladder, and appendix
Procedure:	Pancreaticoduodenectomy (Whipple resection), total pancreatectomy, partial gastrectomy, cholecystectomy and appendectomy
TUMOR FEATURES:	
Tumor site:	Pancreatic head and body.
Tumor size:	Greatest dimension: 4.5 cm. Additional dimensions: 4 x 2.5 cm
Histologic type:	Ductal adenocarcinoma
Histologic grade:	Poorly differentiated
Lymphovascular invasion:	Not identified
Perineural invasion:	Present
Tumor extension:	Tumor invades ampulla of Vater, duodenal wall, and extends into duodenal mucosa and peripancreatic soft tissue.
Treatment effect:	Not applicable.
LYMPH NODES:	Eight of twenty-four lymph nodes, positive for metastatic carcinoma (8/24).
MARGIN EVALUATION:	POSITIVE (R1)
Distance to closest margin:	Tumor focally extends to inferior-anterior margin.
Other margins:	Uninvolved by invasive carcinoma
PATHOLOGIC TUMOR STAGING DESCRIPTORS:	
Primary tumor:	pT3 (tumor involves ampulla of Vater, duodenal wall, duodenal mucosa, and peripancreatic soft tissue)
Regional lymph nodes:	pN1 (8/24 lymph nodes).
Distant metastasis:	Not applicable.
Margin status:	R1 (tumor focally involves inferior-anterior margin)
Pathologic stage:	IIB
Additional pathologic findings:	Acute and chronic pancreatitis Pancreatic intraepithelial neoplasia (PanIN), grade 3

[page 3 of 5]
FINAL SURGICAL PATHOLOGY REPORT

Source of Specimen:

- A. Gallbladder
- B. Appendix
- C. Lymph node; Celiac
- D. Whipple
- E. Body and tail of pancreas

Clinical History/Operative Dx:

Pancreatic lesion.

Intraoperative Diagnosis:

- D. FSD1: Whipple procedure: Pancreatic margin positive.
FSD2: Bile duct and portion of pancreatic margin: Bile duct negative

Gross Description:

A. The specimen is labeled gallbladder and is received in formalin. It consists of an intact gallbladder which is 10.7 cm in length and has a maximum diameter of 4.8 cm at the fundus. The free serosal surface is pale violet, smooth and shiny. The cystic duct is slightly angulated and slightly thick-walled but the cystic duct is patent. There is a 0.7 cm firm cystic duct node. The gallbladder wall is 0.3 cm in thickness. The mucosa is tan to pale green and velvety to finely nodular. There are no calculi present. Representative sections are submitted in cassette A1

B. The specimen is labeled appendix and is received in formalin. It consist of a C-shaped appendix which is 4.5 cm in length and has a maximum diameter centrally of 0.7 cm. The serosal surface is tan, smooth and shiny. The appendiceal wall is intact. The mesoappendix is unremarkable. The proximal margin is inked. Sections are unremarkable. Representative sections are submitted in cassette B1

C. The specimen is labeled celiac lymph node and is received in formalin. It consists of a roughly ovoid fragment of fibrofatty tissue which is 2 cm in maximum dimension. It appears to contain four discrete lymph nodes, the largest of which measures 1.6 x 0.7 x 0.4 cm and the smallest node is 0.4 cm in maximum dimension. The two largest nodes are inked with contrasting colors. They are serially sectioned and submitted in cassette C1. The two smaller nodes are inked with contrasting colors. They are sectioned and submitted in cassette C2.

Page 2
Total Pages: 2

[page 4 of 5]
FINAL SURGICAL PATHOLOGY REPORT

D. The specimen is labeled Whipple procedure and is received without fixative. It consists of a composite resection which includes a 12.5 x 6 x 2.5 cm portion of gastric tissue and a 21 cm segment of duodenum. The proximal and distal margins are stapled. The free serosal surface of the gastric portion is reddish-violet and smooth with a small amount of perigastric adipose tissue. A prominent lymph node is adherent to the pyloric portion of the resection. Just distal to the pylorus, there is a hard 6 x 4.8 x 2.3 cm portion of pancreatic tissue. There are several posteriorly located peripancreatic lymph nodes which are up to 1.5 cm in maximum dimension. Along the posterior-superior edge of the pancreatic tissue, there is a 3.8 cm segment of markedly dilated bile duct which is up to 1.3 cm in diameter. The bile duct margin and the distal pancreatic margin are removed and submitted for frozen section. The bile duct is opened to reveal a braided metallic stent within the lumen of the bile duct. The anterior-superior surface of the pancreas is inked blue, the anterior-inferior and uncinate portion of the pancreas is inked green, and the posterior surface is inked black. The free serosal surface of the duodenum is reddish-violet with stringing fibrous adhesions but the duodenal wall appears intact. The specimen is opened to reveal the gastric mucosa has small irregular rugal folds and is dark red and hyperemic throughout. The pylorus is 3.5 cm in diameter and shows similar dark red hemorrhagic discoloration. Hemorrhagic discoloration extends 2.5 cm distal to the pylorus in the proximal duodenal mucosa. The ampulla of Vater is located 7.5 cm distal to the pylorus and a braided metallic stent is present at the ampulla. The underlying pancreatic tissue is prominently firm and on sectioning, the head of the pancreas is nearly completely replaced by a firm pale tan to pale yellow neoplasm which is focally centrally necrotic. This neoplasm overall measures 4.5 x 4 x 2.5 cm. The neoplasm appears to encircle the ampulla but does not grossly appear to extend into the duodenal mucosa surrounding the ampulla. The neoplasm is 9.5 cm from the distal margin and 14.5 cm from the proximal margin. The neoplasm abuts the anterior and posterior surfaces of the pancreas and appears present at the distal pancreatic resection margin grossly. The distal duodenal mucosa is pale red but shows normal appearing mucosal folds and there is a submucosal pale yellow, 0.4 cm nodule located 3 cm distal to the ampulla. No other mucosal lesions are identified within the duodenum. There is very little adherent peripancreatic fat. Following fixation, representative sections are submitted. Section summary: D1) distal pancreatic margin from frozen section, D2) bile duct margin and portion of pancreatic margin from frozen section, D3-D4) proximal gastric margin, D5) representative gastric tissue from fundus, D6) representative pylorus, D7) proximal duodenal mucosa just distal to pylorus, D8-D9) sections of ampulla and peri-ampullary mucosa (stent has been dislodged), D12-D13) anterior-inferior surface of pancreas, D14) posterior surface of pancreas, D15-D16) representative pancreatic tumor, D17-D18) sections of pancreatic tumor and bile duct as it enters the pancreas, D19) small duodenal submucosal lesion distal to ampulla, D20) distal duodenal margin, D21) lymph node at pylorus, D22) largest peripancreatic node and adjacent pancreatic tumor, D23) additional posterior peripancreatic lymph node, D24) additional posterior peripancreatic lymph node, D25-D26) additional possible peripancreatic nodes. [REDACTED]

E. The specimen is labeled body and tail of pancreas and is received in formalin. It consists of a roughly elliptical portion of pancreatic tissue which weighs 11 grams. Black sutures are present at one end of the specimen and mark the body of the pancreas. The external surface varies from smooth to slightly disrupted near the tail of the pancreas. The entire external surface is inked. The specimen is serially sectioned perpendicular to the long axis to reveal it is composed of moderately firm pale yellow tissue with a central hemorrhagic appearing tubular structure which courses nearly through the entire specimen. Well-delineated tumor is not appreciated grossly. The specimen is sequentially and entirely submitted as summarized below. Section summary: E1) head of pancreas as en face section, E2-E8) sections progressing toward tail, E9) tail as perpendicular sections. [REDACTED]

[REDACTED]

[page 5 of 5]
FINAL SURGICAL PATHOLOGY REPORT

Microscopic Description:

A. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

B. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

C. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

D. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

E. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

Source: NCI Genomic Data Commons file 2b3f6dbb-a3c7-4991-bbe9-a195b1904096 (TCGA-HZ-8005.866AF8EE-52C6-48F2-A385-E3CAD487C401.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).